Gene-level copy-number profile of tumor specimen C3L-03378-04 from CPTAC case C3L-03378, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.8 years (20,019 days).
Specimen C3L-03378-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dec0fe39-5ed6-45f0-87d3-6e3ada7870b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03378-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/76ed3581-c104-4fc3-b786-f1960cf9405a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 510; copy number 1: 762; copy number 2: 9,503; copy number 3: 17,716; copy number 4: 23,864; copy number 5: 1,603; copy number 6: 39; copy number 7: 4,480; copy number 8: 78; copy number 9: 264; copy number 10: 44; copy number 12: 8; copy number 13: 37.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:25,120,014–25,279,204, 4 genes (within-gene range 0–3): SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1.
- chr6:29,887,294–29,908,645, 5 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,892,188–22,128,103, 10 genes (within-gene range 0–3): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:87,751,512–88,700,401, 16 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 345 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,642,494, 10 genes, copy number 10: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr22:29,058,672–37,315,341, 264 genes, copy number 9 (broad region; genes not listed).
- chr22:38,818,452–40,044,530, 43 genes, copy number 10–13: NPTXR, CBX6, AL022318.1, APOBEC3A, APOBEC3B, APOBEC3B-AS1, APOBEC3C, AL022318.4, APOBEC3D, APOBEC3F, AL022318.2, APOBEC3G, AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1, MGAT3, MGAT3-AS1, MIEF1, AL022312.1, ATF4, RPS19BP1, CACNA1I, ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1.
- chr22:41,367,333–41,926,806, 28 genes, copy number 10: TEF, RNU6-495P, AL008582.1, TOB2, ACO2, PHF5A, POLR3H, AL023553.1, CSDC2, PMM1, DESI1, XRCC6, Y_RNA, SNU13, Z83840.1, RNU6-476P, C22orf46, MEI1, HMGN2P10, RNU6ATAC22P, Y_RNA, CCDC134, SREBF2-AS1, SREBF2, MIR33A, SHISA8, TNFRSF13C, MIR378I.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
